Somatic mutation profile of tumor specimen TCGA-CK-4950-01A (aliquot TCGA-CK-4950-01A-01D-1719-10) from TCGA case TCGA-CK-4950, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.3 years (24,944 days).
Specimen TCGA-CK-4950-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e91e5d73-03ab-4aba-a524-829dbf5e9c73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-4950-10A (Blood Derived Normal), aliquot TCGA-CK-4950-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd5b5bb7-4e91-4c25-803c-6184dacb930b

The open-access MAF lists 195 somatic variants for this specimen: 142 protein-altering or splice-affecting, 49 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 49, Nonsense Mutation 11, Frame Shift Del 5, Intron 3, Frame Shift Ins 2, Splice Region 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 37/145 reads (26%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 40/111 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCBP1 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 16/100 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57850093, COSV57850258, COSV57850830; called by muse, mutect2
- SMAD4 | c.906G>A p.W302* | Nonsense Mutation (SNP) | VAF 39/229 reads (17%) | catalogued as rs878854769, COSV61688760; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TRPV6 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1281361203, COSV63892531; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4287C>A p.N1429K | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV70034046; called by muse, mutect2, varscan2
- ABCD4 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778062723, COSV53990914; called by muse, mutect2, varscan2
- AKR1C4 | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as COSV54124133; called by muse, mutect2, varscan2
- AMER1 | c.1876C>T p.R626* | Nonsense Mutation (SNP) | VAF 39/125 reads (31%) | catalogued as rs1408150272, COSV57655083; called by muse, mutect2, varscan2
- ANK2 | c.3309C>A p.D1103E | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.54); catalogued as COSV100005013, COSV52172412; called by muse, mutect2, varscan2
- ANK2 | c.8187G>T p.E2729D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV52172437; called by muse, mutect2, varscan2
- ARHGAP36 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 52/331 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52268977; called by muse, mutect2, varscan2
- ATP10A | c.4376C>T p.T1459M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs537766555, COSV63514270; called by muse, mutect2
- ATP6V0A4 | c.1732C>A p.P578T | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59477683; called by muse, mutect2, varscan2
- ATRX | c.6563G>C p.R2188P | Missense Mutation (SNP) | VAF 75/423 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64879508, COSV64879971; called by muse, mutect2, varscan2
- BAIAP3 | c.2548G>C p.D850H | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.27); catalogued as COSV50104406; called by muse, mutect2, varscan2
- CACNA1G | c.4810G>A p.V1604I | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1177958111, COSV61731678; called by muse, mutect2, varscan2
- CFAP54 | c.8149G>T p.A2717S | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV61575743; called by muse, mutect2, varscan2
- CFH | c.20T>C p.I7T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV62778122; called by muse, mutect2, varscan2
- CNDP1 | c.710C>G p.P237R | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62594237, COSV62594414; called by muse, mutect2, varscan2
- COL2A1 | c.4264C>T p.R1422W | Missense Mutation (SNP) | VAF 54/341 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754466377, COSV61527665; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- COL5A1 | c.4432C>T p.P1478S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.138); catalogued as COSV100880070; called by muse, mutect2
- COQ9 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 33/122 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.101); catalogued as rs754267013, COSV52646499; called by muse, mutect2, varscan2
- CRACR2A | c.208A>T p.I70F | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52915316; called by muse, mutect2, varscan2
- CTTN | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57233919; called by muse, mutect2, varscan2
- DCLK1 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs373107227; called by muse, mutect2, varscan2
- DHODH | c.822G>A p.L274= | Splice Region (SNP) | VAF 59/217 reads (27%) | catalogued as COSV54662891; called by muse, mutect2, varscan2
- DNAH3 | c.4022C>T p.T1341M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs374637987; called by muse, mutect2, varscan2
- EFCAB1 | c.443A>T p.D148V | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50618868; called by muse, mutect2, varscan2
- ELMO1 | c.415C>T p.R139* | Nonsense Mutation (SNP) | VAF 29/93 reads (31%) | catalogued as COSV60312444; called by muse, mutect2, varscan2
- ERICH3 | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1365373663, COSV58605892; called by muse, mutect2, varscan2
- FAM47A | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.697); catalogued as rs375344520, COSV60498157; called by muse, varscan2
- FGA | c.1978dup p.S660Ffs*27 | Frame Shift Ins (INS) | VAF 21/127 reads (17%) | catalogued as rs757027534; called by mutect2, pindel, varscan2
- FIG4 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 71/267 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.134); catalogued as COSV57788949; called by muse, mutect2, varscan2
- FLNC | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 83/262 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs776881635, COSV57950302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMNL2 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs377550607; called by muse, mutect2, varscan2
- FTSJ1 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs782303332, COSV50026060; called by muse, mutect2, varscan2
- FUT2 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as COSV67179511; called by muse, mutect2
- GATA4 | c.1097C>T p.T366M | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs781198110, COSV58734459, COSV58735180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GEMIN8 | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 58/312 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV60550895; called by muse, mutect2, varscan2
- GJB1 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as CM024344, COSV62139759; called by muse, mutect2, varscan2
- GLUD2 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV60152410; called by mutect2, varscan2
- GPR68 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.947); catalogued as rs149975079; called by muse, mutect2, varscan2
- GRB10 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV60012811; called by muse, mutect2, varscan2
- HIVEP1 | c.1631A>C p.D544A | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.611); catalogued as COSV65103189; called by muse, mutect2, varscan2
- IFNL2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781235388, COSV59593761; called by muse, mutect2, varscan2
- ING1 | c.165C>G p.N55K | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.056); catalogued as rs200535822, COSV58170461; called by muse, mutect2, varscan2
- INPP5D | c.2855C>T p.P952L (on ENST00000445964 / NM_001017915.3; = p.P951L on NM_005541.5) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as rs375229594; called by muse, mutect2, varscan2
- IQCG | c.1268T>C p.V423A | Missense Mutation (SNP) | VAF 100/476 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.014); catalogued as COSV54563535, COSV54563601; called by muse, mutect2, varscan2
- KCNH7 | c.1463T>C p.I488T | Missense Mutation (SNP) | VAF 65/463 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59803362, COSV59814483; called by muse, mutect2, varscan2
- KCNMB2 | c.14C>A p.T5N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.587); catalogued as COSV64201460; called by muse, mutect2, varscan2
- KLHL13 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 71/499 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1415625316, COSV53244873, COSV53250063; called by muse, mutect2, varscan2
- KRTAP4-4 | c.194G>T p.C65F | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV66811411; called by muse, mutect2, varscan2
- LYZL1 | c.68C>T p.T23I | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as COSV64966672; called by muse, mutect2, varscan2
- MAB21L1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59800229; called by muse, mutect2, varscan2
- MAN1A1 | c.1670G>A p.R557K | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV63788182; called by muse, mutect2, varscan2
- MAP2K7 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67608916; called by muse, mutect2, varscan2
- MATK | c.99G>A p.W33* (on ENST00000310132 / NM_139355.3; = p.W34* on NM_002378.4) | Nonsense Mutation (SNP) | VAF 37/153 reads (24%) | catalogued as COSV59555648; called by muse, mutect2, varscan2
- MEIOC | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as rs750092529, COSV63440581; called by muse, mutect2, varscan2
- MOV10L1 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 44/214 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV99434101; called by muse, mutect2, varscan2
- MTUS1 | c.1500A>G p.I500M | Missense Mutation (SNP) | VAF 74/411 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV50566601; called by muse, mutect2, varscan2
- MTX3 | c.492A>T p.E164D | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV72512407; called by muse, mutect2, varscan2
- MXRA5 | c.2129C>A p.T710N | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as rs201138126, COSV99477480; called by muse, mutect2, varscan2
- MYH8 | c.5164C>A p.Q1722K | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV67968345; called by muse, mutect2, varscan2
- MYO15A | c.6553C>A p.Q2185K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52760286; called by muse, mutect2, varscan2
- NLRP4 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as rs1175246779, COSV56709262, COSV56719853; called by muse, mutect2
- OR13C9 | c.898A>C p.N300H | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52242782; called by muse, mutect2, varscan2
- OR5AR1 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 51/256 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs780660808, COSV57254597; called by muse, mutect2, varscan2
- PAIP1 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 115/525 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59086510; called by muse, mutect2, varscan2
- PCLO | c.13810C>A p.L4604I | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as COSV61647697; called by muse, mutect2, varscan2
- PCNT | c.5146G>T p.E1716* | Nonsense Mutation (SNP) | VAF 61/226 reads (27%) | catalogued as COSV100855638; called by muse, mutect2, varscan2
- PCSK1 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (1); PolyPhen possibly damaging (0.62); catalogued as rs758046584, COSV60733679; called by muse, mutect2, varscan2
- PDGFA | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1243534394, COSV63279970; called by muse, mutect2
- PDGFRA | c.2692G>A p.G898S | Missense Mutation (SNP) | VAF 131/521 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as rs1185214354, COSV57270536, COSV57274438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDIA5 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1383941343, COSV60250387; called by muse, mutect2, varscan2
- PFKFB1 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 44/232 reads (19%) | PolyPhen possibly damaging (0.897); catalogued as rs771482577, COSV66628844; called by muse, mutect2, varscan2
- PHKA2 | c.2665G>A p.V889I | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.106); catalogued as rs199948654, COSV66055003; called by muse, mutect2, varscan2
- PIP4P2 | c.111del p.E37Dfs*19 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as COSV53439452; called by mutect2, varscan2
- PIP5K1A | c.659G>C p.R220P (on ENST00000368888 / NM_001135638.2; = p.R207P on NM_003557.3) | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV62959058, COSV62959459; called by muse, mutect2, varscan2
- PLXNB2 | c.3959C>T p.S1320F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63781403; called by muse, varscan2
- PNPLA8 | c.2009C>T p.T670M | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.247); catalogued as rs778206359, COSV57553576; called by muse, mutect2, varscan2
- POLRMT | c.3602C>T p.A1201V | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as COSV52116665; called by muse, mutect2
- PPM1N | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749736288, COSV55595009; called by muse, mutect2, varscan2
- PREX2 | c.3445C>T p.R1149C | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.88); catalogued as rs371787029, COSV55755479; called by muse, mutect2, varscan2
- PSAPL1 | c.1475G>T p.S492I | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV59843635; called by muse, mutect2, varscan2
- PSD4 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs1425942029, COSV55526901; called by muse, mutect2, varscan2
- PTBP2 | c.355G>T p.V119F (on ENST00000426398 / NM_001300986.2; = p.V111F on NM_021190.4) | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100930223; called by muse, mutect2, varscan2
- PTPRZ1 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as rs1469276203, COSV66432630; called by muse, mutect2, varscan2
- RBM48 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs770384798, COSV50404229; called by muse, mutect2, varscan2
- RGS12 | c.1303A>G p.S435G | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs1200928068, COSV100375792; called by muse, mutect2
- RIMS1 | c.4207G>T p.G1403* | Nonsense Mutation (SNP) | VAF 30/120 reads (25%) | catalogued as COSV99327722; called by muse, varscan2
- RIPOR2 | c.299C>A p.T100K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52424894; called by muse, mutect2, varscan2
- RNF139 | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52681573; called by muse, mutect2, varscan2
- RYR2 | c.8408G>A p.R2803Q | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs780643623, COSV63698303; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.11981C>T p.A3994V | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.881); catalogued as rs759166886, COSV66539582; called by muse, mutect2, varscan2
- SAG | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV68591531, COSV68592244; called by muse, mutect2, varscan2
- SATL1 | c.1069C>T p.R357* (on ENST00000395409; = p.R544* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 49/265 reads (18%) | catalogued as COSV60576027, COSV60576401; called by muse, mutect2, varscan2
- SCAMP1 | c.381T>G p.F127L | Missense Mutation (SNP) | VAF 99/485 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.225); catalogued as COSV100210506; called by muse, mutect2, varscan2
- SCNN1G | c.1290C>A p.N430K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV55600015; called by muse, mutect2, varscan2
- SERTAD4 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as COSV65399737; called by muse, varscan2
- SLC4A2 | c.1789G>C p.D597H | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59658138, COSV59659526; called by muse, mutect2, varscan2
- SLC9A2 | c.782G>T p.C261F | Missense Mutation (SNP) | VAF 167/488 reads (34%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.957); catalogued as COSV52134045; called by muse, varscan2
- SLITRK6 | c.1796del p.R599Hfs*12 | Frame Shift Del (DEL) | VAF 23/166 reads (14%) | catalogued as COSV68390277; called by mutect2, pindel, varscan2
- SMAD4 | c.1595C>A p.A532D | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV61684259, COSV61691263; called by muse, mutect2, varscan2
- SOX9 | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 120/282 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV55425853; called by muse, mutect2, varscan2
- SPHKAP | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 204/533 reads (38%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.69); catalogued as COSV60885501; called by muse, mutect2, varscan2
- STK38 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 64/329 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV57709586; called by muse, mutect2, varscan2
- SYNM | c.4298C>T p.A1433V | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs782239415, COSV50442709; called by muse, mutect2, varscan2
- TACC2 | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV57762090; called by muse, mutect2
- TCP11 | c.972G>T p.K324N (on ENST00000512012; = p.K262N on NM_018679.5) | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV55131614; called by muse, mutect2, varscan2
- TDO2 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs1481361495, COSV72232967; called by muse, mutect2, varscan2
- TECTA | c.2810G>A p.R937H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1246577688, COSV50741830, COSV50779559; called by muse, mutect2
- TENM1 | c.1389G>T p.M463I | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV64436646; called by muse, mutect2, varscan2
- TENM4 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs761178978, COSV53644870; called by muse, mutect2, varscan2
- TIAM1 | c.4505C>A p.T1502K | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54560739; called by muse, mutect2, varscan2
- TM9SF3 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV64457857; called by muse, mutect2, varscan2
- TMEM132E | c.199G>C p.A67P | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58698671; called by muse, varscan2
- TOPBP1 | c.1970C>G p.A657G | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV53434042, COSV53438315; called by muse, mutect2, varscan2
- TRIM2 | c.718C>T p.Q240* (on ENST00000437508; = p.Q267* on NM_015271.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/102 reads (25%) | catalogued as COSV58636154; called by muse, mutect2, varscan2
- TRPM3 | c.4987A>C p.K1663Q (on ENST00000357533 / NM_001366142.2; = p.K1518Q on NM_020952.6) | Missense Mutation (SNP) | VAF 56/275 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV62589553; called by muse, mutect2, varscan2
- TRPM8 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.213); catalogued as rs200547297, COSV61222741, COSV61224767; called by muse, mutect2, varscan2
- TTN | c.46739G>A p.R15580H (on ENST00000591111; = p.R8156H on NM_003319.4) | Missense Mutation (SNP) | VAF 100/591 reads (17%) | PolyPhen probably damaging (0.998); catalogued as rs770653436, COSV60175619; called by muse, mutect2, varscan2
- TTN | c.41198C>T p.T13733I (on ENST00000591111; = p.T6309I on NM_003319.4) | Missense Mutation (SNP) | VAF 73/218 reads (33%) | PolyPhen benign (0); catalogued as COSV60175671; called by muse, mutect2, varscan2
- TTN | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | PolyPhen probably damaging (0.999); catalogued as rs757199733, COSV60175700; called by muse, mutect2, varscan2
- UBL7 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as COSV63706439; called by muse, mutect2, varscan2
- UNC45B | c.2120C>G p.P707R | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52097862; called by muse, mutect2, varscan2
- USP29 | c.887T>G p.M296R | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54144331; called by muse, mutect2, varscan2
- USP6NL | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as rs1007903477, COSV53213241; called by muse, mutect2
- USP9X | c.989A>C p.N330T | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV61071677; called by muse, mutect2, varscan2
- WASF3 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.07); catalogued as COSV58968371; called by muse, mutect2, varscan2
- XPO4 | c.2385G>A p.M795I | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs771067742, COSV55009725; called by muse, mutect2, varscan2
- ZCCHC12 | c.1100C>G p.A367G | Missense Mutation (SNP) | VAF 58/278 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV59572285; called by muse, varscan2
- ZCCHC8 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60319019; called by muse, mutect2, varscan2
- ZNF384 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.829); catalogued as rs1006798292, COSV60532617; called by muse, mutect2, varscan2
- ZNF451 | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | catalogued as COSV62597766, COSV62598403; called by muse, mutect2, varscan2
- APC | c.2274dup p.A759Sfs*16 | Frame Shift Ins (INS) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- BSN | c.1906_1907del p.K636Efs*7 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | called by mutect2, pindel, varscan2
- EXO1 | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); called by muse, mutect2
- GTF2IRD2B | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 98/866 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- KIAA0586 | c.4490del p.P1497Lfs*6 (on ENST00000619416 / NM_001244190.2; = p.P1436Lfs*6 on NM_014749.5) | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1364C>A p.P455Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- TTN | c.45394del p.E15132Sfs*22 (on ENST00000591111; = p.E7708Sfs*22 on NM_003319.4) | Frame Shift Del (DEL) | VAF 62/252 reads (25%) | called by mutect2, pindel, varscan2
- ABCA13 | c.5373C>T p.F1791= | Silent (SNP) | VAF 32/165 reads (19%) | catalogued as rs368321892; called by muse, mutect2, varscan2
- ABCA3 | c.2025C>T p.I675= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as rs1434643100, COSV57056219; called by muse, mutect2
- ADAM2 | c.285A>G p.Q95= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as COSV55864791; called by muse, mutect2, varscan2
- ADGRL1 | c.1029C>T p.R343= (on ENST00000340736 / NM_001008701.3; = p.R338= on NM_014921.5) | Silent (SNP) | VAF 37/203 reads (18%) | catalogued as rs1031002208, COSV61565494; called by muse, mutect2, varscan2
- AJAP1 | c.759G>A p.T253= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV65449053; called by muse, mutect2, varscan2
- BOLA1 | c.393G>A p.K131= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV64967356; called by muse, mutect2, varscan2
- COL6A3 | c.2004C>T p.S668= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV99799056; called by muse, mutect2, varscan2
- CPZ | c.1218C>T p.P406= (on ENST00000360986 / NM_001014447.3; = p.P395= on NM_003652.3) | Silent (SNP) | VAF 26/95 reads (27%) | catalogued as rs185645651, COSV59924153; called by muse, mutect2, varscan2
- DDX24 | c.606G>A p.P202= | Silent (SNP) | VAF 27/149 reads (18%) | catalogued as rs770840846, COSV58213051; called by muse, mutect2, varscan2
- DOCK3 | c.2805G>A p.Q935= | Silent (SNP) | VAF 73/349 reads (21%) | catalogued as rs1333168811, COSV56533132; called by muse, mutect2, varscan2
- DUSP10 | c.33A>G p.V11= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV60458639; called by muse, mutect2
- EGR2 | c.30C>T p.I10= | Silent (SNP) | VAF 18/126 reads (14%) | catalogued as COSV54347599; called by muse, mutect2, varscan2
- FUT1 | c.195C>T p.N65= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs763594230, COSV55810775; called by muse, mutect2
- GLI2 | c.3225C>A p.G1075= (on ENST00000361492 / NM_001374353.1; = p.G1092= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV58045817; called by muse, mutect2
- GPLD1 | c.516A>G p.E172= | Silent (SNP) | VAF 29/141 reads (21%) | catalogued as COSV57759079; called by muse, mutect2, varscan2
- GRIA4 | c.2505G>A p.E835= | Silent (SNP) | VAF 24/151 reads (16%) | catalogued as COSV56906532; called by muse, mutect2, varscan2
- HYDIN | c.1351C>A p.R451= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV55491079, COSV55498562; called by muse, mutect2, varscan2
- IGSF3 | c.774G>A p.S258= | Silent (SNP) | VAF 38/191 reads (20%) | catalogued as rs190957846; called by muse, mutect2, varscan2
- KDM4D | c.186C>T p.T62= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV58634981, COSV58635329; called by muse, mutect2, varscan2
- KLHL40 | c.51G>A p.T17= | Silent (SNP) | VAF 44/181 reads (24%) | catalogued as rs1248432981, COSV55135625; called by muse, mutect2, varscan2
- KRTAP13-3 | c.414T>C p.P138= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV61879283, COSV61879730; called by muse, mutect2, varscan2
- LMNTD1 | c.1071A>G p.G357= | Silent (SNP) | VAF 29/197 reads (15%) | catalogued as COSV51448623; called by muse, mutect2, varscan2
- MC4R | c.750G>T p.L250= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV55351876, COSV55352609; called by muse, mutect2, varscan2
- NEK6 | c.378C>T p.D126= | Silent (SNP) | VAF 23/108 reads (21%) | catalogued as rs779446532, COSV57219417; called by muse, mutect2, varscan2
- OR7D4 | c.717C>A p.S239= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV100432763; called by muse, mutect2, varscan2
- PALLD | c.735C>T p.D245= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV54985753; called by muse, mutect2, varscan2
- PCDHA7 | c.1944G>T p.L648= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as COSV65338500; called by muse, mutect2, varscan2
- PLCB1 | c.759G>A p.Q253= | Silent (SNP) | VAF 52/180 reads (29%) | catalogued as COSV62057238; called by muse, mutect2, varscan2
- PLD5 | c.657G>T p.L219= (on ENST00000442594; = p.L157= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/199 reads (17%) | catalogued as rs1308055318, COSV59155339; called by muse, mutect2, varscan2
- PLG | c.1656C>T p.Y552= | Silent (SNP) | VAF 77/348 reads (22%) | catalogued as rs113153850; called by muse, mutect2, varscan2
- PRRT1 | c.54G>A p.P18= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV52998949; called by muse, mutect2, varscan2
- RCBTB2 | c.180C>T p.Y60= | Silent (SNP) | VAF 61/303 reads (20%) | catalogued as COSV60650734; called by muse, mutect2, varscan2
- RNF128 | c.54C>A p.S18= | Silent (SNP) | VAF 21/136 reads (15%) | catalogued as COSV55252488; called by muse, mutect2
- ROBO1 | c.4101G>A p.T1367= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as rs774597124, COSV71391840; called by muse, mutect2, varscan2
- RP1L1 | c.7020C>T p.A2340= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as COSV66757306; called by muse, mutect2, varscan2
- RP1L1 | c.1701G>A p.E567= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV66757319; called by muse, mutect2
- SIGLEC10 | c.1278C>T p.H426= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as rs536361935, COSV59483681, COSV59484019; called by muse, mutect2, varscan2
- SLC22A25 | c.231C>A p.I77= | Silent (SNP) | VAF 54/291 reads (19%) | catalogued as COSV60594821, COSV60597194; called by muse, mutect2, varscan2
- SLC26A7 | c.939C>T p.F313= | Silent (SNP) | VAF 52/211 reads (25%) | catalogued as rs551383153, COSV99403630; called by muse, mutect2, varscan2
- SOX14 | c.690C>T p.D230= | Silent (SNP) | VAF 29/163 reads (18%) | catalogued as COSV60163147; called by muse, mutect2, varscan2
- SOX3 | c.576C>A p.A192= | Silent (SNP) | VAF 68/381 reads (18%) | catalogued as COSV65168413; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.402T>C p.P134= | Silent (SNP) | VAF 50/236 reads (21%) | catalogued as COSV60339820; called by muse, mutect2, varscan2
- SYNE2 | c.16513C>A p.R5505= | Silent (SNP) | VAF 44/202 reads (22%) | catalogued as COSV59953844, COSV59957623; called by muse, mutect2, varscan2
- SYT14 | c.1524A>G p.K508= | Silent (SNP) | VAF 53/276 reads (19%) | catalogued as rs141626974; called by muse, mutect2, varscan2
- TLE4 | c.489C>T p.I163= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as rs555373051, COSV54635504; called by muse, mutect2, varscan2
- TROAP | c.1566C>G p.P522= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV99226894; called by muse, mutect2, varscan2
- ZCCHC12 | c.1161G>A p.R387= | Silent (SNP) | VAF 49/254 reads (19%) | catalogued as COSV59571722; called by muse, varscan2
- ZNF816 | c.42G>A p.E14= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as rs1246580696, COSV54411680; called by muse, mutect2, varscan2
- ZW10 | c.183C>G p.T61= | Silent (SNP) | VAF 38/189 reads (20%) | catalogued as COSV52317795; called by muse, mutect2, varscan2
- COL6A2 | c.2461+2701G>A | Intron (SNP) | VAF 18/126 reads (14%) | catalogued as rs745706017, COSV56010288; called by muse, mutect2
- IDH3G | c.*2C>T | 3'UTR (SNP) | VAF 19/112 reads (17%) | catalogued as COSV99473226; called by muse, mutect2
- TCF7L2 | c.1442+643G>A | Intron (SNP) | VAF 52/223 reads (23%) | catalogued as COSV99526046; called by muse, mutect2, varscan2
- TRIM61 | c.526-2073C>T | Intron (SNP) | VAF 52/249 reads (21%) | catalogued as COSV61418486; called by muse, mutect2
